TCGA case TCGA-QQ-A8VH — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nerve Sheath Tumors; Primary site: Retroperitoneum and peritoneum; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5a2b2e1b-b631-40ae-ba41-d8022cddb550

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Dead; Days to death: 320 days.

Diagnoses (3)
1. Malignant peripheral nerve sheath tumor (the primary disease): ICD-O-3 morphology code: 9540/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 31.8 years (11,599 days); Year of diagnosis: 2010; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 3.3; Tumor length measurement: 1.8; Tumor width measurement: 4.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No.
2. Recurrence of diagnosis 1 (Malignant peripheral nerve sheath tumor), site: Vertebral column. Age at diagnosis: 32.3 years (11,796 days); Days to diagnosis: 197 days; Prior treatment: Yes.
   Pathology details: Measurement type: Pathologic; Tumor burden: 11.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4.5; Tumor length measurement: 11; Tumor width measurement: 8.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.
3. Subsequent primary of the vertebral column (histology not recorded by GDC). Age at diagnosis: 32.6 years (11,913 days); Days to diagnosis: 314 days; Prior treatment: Yes.

Follow-up (2 entries)
- Day 197 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Vertebral column; Days to recurrence: 197 days.
- Days to follow up: 320 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A8VH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-QQ-A8VH-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A8VH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A8VH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Malignant Peripheral Nerve Sheath Tumors (MPNST); Site of primary tumor other: Spinal T6 Canal, right pleural cavity; Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Contiguous organ invaded: No.
- Primary pathology, Synovial sarcoma: Mpnst nf indicator: NF1; Mpnst nf familial or sporadic: Sporadic; Mpnst plexiform neurofibroma site: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Chest - Other (please specify.
- Radiation treatment: Days from index date to radiation therapy started: 117; Days from index date to radiation therapy ended: 155; Radiation therapy type: External; Radiation total dose: 56; Radiation adjuvant units: Gy; Radiation adjuvant fractions total: 28; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No; Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 320 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 320 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 197 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A8VH-01A-11D-A37B-01): tumor purity 0.91, ploidy 1.88, whole-genome doublings 0.
